Gene-level copy-number profile of tumor specimen C3L-06639-01 from CPTAC case C3L-06639, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.0 years (25,207 days).
Specimen C3L-06639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f98fff70-01f2-4f18-b85c-34b29495fbee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06639-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/662a8198-b8c7-45b2-a5ad-eca6d22e640d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 15,275; copy number 2: 37,092; copy number 3: 5,309; copy number 4: 511; copy number 5: 154; copy number 6: 275; copy number 7: 7; copy number 8: 31; copy number 9: 53; copy number 10: 77; copy number 13: 6.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene (within-gene range 0–1): U3.
- chr14:21,924,063–22,552,156, 111 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 603 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–522,928, 16 genes, copy number 5–9: OR4G4P, OR4G11P, OR4F5, AL627309.3, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr7:116,524,994–116,922,049, 7 genes, copy number 6 (within-gene range 2–6): CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1.
- chr8:145,047,860–145,066,685, 2 genes, copy number 5: AC139103.1, C8orf33.
- chr13:29,918,647–40,921,774, 162 genes, copy number 5–9 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr18:7,231,125–9,285,985, 31 genes, copy number 5–6 (within-gene range 2–8): LRRC30, AP005270.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA.
- chr20:44,106,590–54,859,812, 265 genes, copy number 6–13 (broad region; genes not listed).
- chr20:57,161,822–57,282,998, 4 genes, copy number 8: AL157414.3, BMP7, BMP7-AS1, AL122058.1.
- chr20:59,852,667–60,814,211, 14 genes, copy number 6: RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1.
- chr21:12,999,676–13,120,807, 5 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:20,314,238–21,700,015, 93 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
